Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HO, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HO-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. GONADAL VASCULAR MARGIN, BIOPSY:
Free of tumor.
- B. LEFT RADICAL RESECTION OF RETROPERITONEAL SARCOMA, LEFT NEPHRECTOMY, DISTAL PANCREATECTOMY, AND ADRENALECTOMY:
Dedifferentiated liposarcoma (see comment).
Tumor measures 25 x 15 x 8 cm.
Tumor focally involves the distal pancreas and approaches to the adrenal gland and kidney.
Surgical margins (renal artery and vein margin, ureteral margin, pancreatic margin, splenic vein and artery margin, and peritoneal margin) are free of tumor; however, the peritoneal margin is less than 1 mm.
Adrenal gland and pancreatic tissue have no significant pathologic findings.
Benign multiloculated supercapsular renal cyst is identified, an incidental finding.
- C. ADDITIONAL RETROPERITONEAL MARGIN, BIOPSY:
Free of tumor.
- D. LATERAL MARGIN, BIOPSY:
Free of tumor.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed
Out by _____

Comment

The tumor is composed of well-differentiated liposarcoma component and dedifferentiated component. The dedifferentiated portion is of spindle cells with marked nuclear pleomorphism and frequent mitotic activity in the background of inflammation. Tumor necrosis is present.

Specimen(s) Received

- A GONADAL VASCULAR MARGIN
B LEFT RADICAL RESECTION OF RETROPERITONEAL SARCOMA, LEFT NEPHRECTOMY, DISTAL
C ADDITIONAL RETROPERITONEAL MARGIN
D LATERAL MARGIN

Clinical History

Sarcoma (retroperitoneal).

ICD-O-3
Liposarcoma, dedifferentiated
8858/3
Site: Retroperitoneum
C48.0
J 4/22/14

[page 2 of 3]
Preoperative Diagnosis

Not given.

Gross Description

A. The specimen is labeled "gonadal vascular margin." The specimen consists of an unoriented fragment of blood vessel measuring 0.7 cm in length and 0.2 cm in diameter. There is a moderate amount of adipose tissue attached to the blood vessel. The specimen is serially sectioned and submitted entirely in 4 cassettes, A1-A4.

B. The specimen is labeled "left radical resection of retroperitoneal sarcoma, left nephrectomy, distal pancreatectomy, splenectomy, adrenalectomy, stitch marks pancreatic margin." The specimen consists of a left total nephrectomy (11 x 6 x 4.5 cm weighs 160 g), left adrenalectomy (5.5 x 2 x 0.3 cm), distal pancreatectomy (4.5 x 4 x 1.5 cm), splenectomy 8 x 6 x 3 cm weighs 102 g). Adjacent to the splenic hilum, there is a portion of greater omentum, which measures 15 x 12 x 1 cm. The kidney and adrenal gland are surrounded by a large amount of retroperitoneal lobulated adipose tissue ranging from 1 to 3.5 cm in thickness. The specimen measures in overall dimension 25 x 15 x 8 cm and weighs 1889 g. Vascular, ureteral and pancreatic resection margins are stapled. Prior to sectioning, the specimen is inked as follows:

Anterior aspect of the distal pancreas: Green

Stapled pancreatic resection margin: Black

The remainder of the retroperitoneal adipose tissue resection margin and peritoneum: Blue.

On sectioning, the perinephric adipose tissue adjacent to the superior pole of the kidney reveals an irregular-to-roughly ovoid, rubbery, solid, ill-defined tumor, which measures 4.8 x 4.5 x 3.7 cm. The tumor focally involves the cortex of adrenal gland, distal pancreas, and extends to within 1 cm of the closest pancreatic stapled resection margin and 1.5 cm of the closest retroperitoneal adipose tissue resection margin. The tumor bulges but does not appear to extend through the peritoneum covering anterior aspect of the specimen. The tumor is 1 cm from the renal capsule of the superior pole of the kidney. Cut section of the tumor is tan, homogenous without evidence of necrosis or hemorrhage. The remainder of the adrenal gland and pancreatic parenchyma are grossly unremarkable. On sectioning, the remainder of retroperitoneal adipose tissue reveals a pale yellow, lobulated, grossly unremarkable cut surface. On sectioning, the kidney reveals a single subcapsular cystic lesion, which is located in the inferior pole measuring 2 cm in diameter. The cyst is filled with a moderate amount of tan-brown fluid. Inner wall of the cyst is tan, smooth, and glistening. The remainder of the renal parenchyma is grossly unremarkable. Attached to the kidney is 4 cm length of ureter, which is grossly unremarkable. Upon opening the renal pelvis and calix exhibit tan, smooth, glistening urothelium. The renal artery and vein and their branches are grossly unremarkable. There are portions of splenic artery and vein attached to the spleen averaging 3 cm in length. The resection margins of the splenic artery and vein are stapled and located 2.5 cm from the tumor. On sectioning, the spleen reveals a single, irregular, subcapsular hematoma, which measures 2.5 x 3 x 0.5 cm. The remaining splenic pulp is dark red-brown, and grossly unremarkable. No lymph nodes are identified within the hilum of the spleen and the kidney. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 30 cassettes as follows:

B1: Renal artery and vein.

B2: Resection margin of the ureter.

B3-B4: Tangential section of the pancreatic parenchymal resection margin.

[page 3 of 3]
B5: Resection margins of the splenic artery and vein.
B6-B12: Tumor involving adrenal gland.
B13-B16: Additional sections of the tumor with overlying peritoneum.
B17-B21: Tumor involving distal pancreas.
B22-B23: Retroperitoneal adipose tissue resection margin closest to the tumor, perpendicular section.
B24: Tumor in relation to the superior pole of the kidney.
B25-B26: Subcapsular renal cyst.
B27-B28: Subcapsular splenic hematoma.
B29-B30: Additional sections of the perinephric adipose tissue, posterior aspect.

C. The specimen is labeled "additional retroperitoneal margin." The specimen consists of multiple, irregular, unoriented fragments of pale-yellow, lobulated, focally hemorrhagic adipose tissue measuring 8 x 6 x 2.5 cm in aggregate. There are foci of hemorrhage ranges from 0.1 to 1.5 cm in greatest dimension. No residual tumor or other lesions are grossly identified. Representative sections of the specimen are submitted in 4 cassettes, C1-C4.

D. The specimen is labeled "lateral margin." The specimen consists of an irregular, unoriented fragment of lobulated adipose tissue measuring 3 x 1.5 x 0.6 cm. Prior to sectioning, the specimen is inked black. The specimen is serially sectioned and is submitted entirely in 4 cassettes, D1-D4.

Source: NCI Genomic Data Commons file 936272ef-ed40-4192-bf63-62a5cfb3d55d (TCGA-3B-A9HO.2AC232C3-BE7A-44A1-ADCD-F052216D6E96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).